CGCI case HTMCP-03-06-02238 — HIV+ Tumor Molecular Characterization Project - Cervical Cancer (CGCI-HTMCP-CC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/796408b3-5f54-4ef5-afeb-b224fc0eb3e6

Demographics
Sex at birth: female; Race: black or african american; Age at index: 40 years; Vital status: Dead; Days to death: 614 days (1.7 years).

Diagnoses (1)
1. Squamous cell carcinoma, keratinizing, NOS: ICD-O-3 morphology code: 8071/3; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 40.9 years (14,943 days); Year of diagnosis: 2015; Method of diagnosis: Biopsy; AJCC clinical T: T2b; AJCC clinical N: NX; AJCC clinical M: MX; FIGO stage: Stage IIB; FIGO staging edition year: 2009; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 614 days (1.7 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 20 days; Days to treatment end: 41 days; Treatment dose: 45; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Initial Diagnosis; Days to treatment start: 26 days; Days to treatment end: 40 days; Number of cycles: 3; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Paclitaxel; Days to treatment start: 91 days; Days to treatment end: 199 days; Number of cycles: 6; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Brachytherapy, Low Dose; Treatment intent type: Adjuvant; Treatment dose: 3000; Treatment outcome: Complete Response; Treatment anatomic sites: Cervix.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Treatment dose: 3; Treatment outcome: Complete Response; Chemo concurrent to radiation: Yes; Treatment frequency: Once Weekly.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Treatment dose: 4500; Treatment outcome: Complete Response; Treatment anatomic sites: Pelvis.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Treatment dose: 0; Treatment outcome: Complete Response; Treatment anatomic sites: Lymph Node(s) Paraaortic.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (5 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 316 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Cervix uteri; Days to recurrence: 316 days.
- Days to follow up: 357 days; Disease response: With Tumor.
- Days to follow up: 614 days (1.7 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day -694.

Molecular and laboratory tests
- CDKN2A (IHC): Positive.

Other clinical attributes
- Day -694: Risk factors: HIV/AIDS.
- Day -694: Comorbidities: HIV/AIDS.
- Day 0: Weight: 74.7 kg; Height: 179 cm; BMI: 23.3; CD4 count: 313; Haart treatment indicator: Yes; HIV viral load: 34; Hormonal contraceptive use: Former User; Hysterectomy type: Not Performed; Menopause status: Premenopausal; Pregnant at diagnosis: No.
- Day 0: Pregnancy outcome: Miscarriage.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-03-06-02238-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-03-06-02238-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-03-06-02238-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 2; Pregnancies count miscarriage: 1; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Total pregnancy count: 3; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Squamous Cell Carcinoma, Keratinizing; Keratinization squamous cell: Keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Hysterectomy Performed Ind-3: No; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: Year of HIV diagnosis: 2013; Haart therapy at diagnosis: Yes; Haart therapy prior to diagnosis: Yes.
- Follow-up form 1: Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes.
- Follow-up form 1, Treatment, Radiation therapy info: Brachytherapy type: LDR; Radiation therapy xrt type: External beam radiation; Radiation therapy dose paraaortic nodes: 0.
- Follow-up form 1, Treatment, Concurrent prescription treatment info, Concurrent prescription treatment: Chemo concurrent dose: 62; Pharmaceutical treatment dose units: mg; Chemo concurrent fractions total: 3.
- Follow-up form 1, New tumor event: New tumor event type: Locoregional Recurrence; New tumor event site other: Cervix; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Treatments, Treatment 1: Chemo end reporting period: Yes; Pharmaceutical regimen: Paclitaxel + Cisplatin; Pharma adjuvant cycles count: 6.
- Treatments, Treatment 2: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Single Agent Therapy (please specify); Pharma adjuvant cycles count: 3.
- Treatments, Treatment 3: Therapy regimen: Initial; Treatment type: Radiation Therapy; Radiation therapy end: Yes; Radiation therapy total dosage: 45.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02238-01A-01R-6925:
- % tumour top: 80
- % tumour bottom: 80

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02238-01A-01D-6925:
- % tumour top: 80
- % tumour bottom: 80

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02238-10A-01D-6925:
- % tumour top: 0
- % tumour bottom: 0
